Somatic mutation profile of tumor specimen MBCProject_3717_T1_WES (aliquot MBCProject_3717_T1_WES_1) from CMI case MBCProject_3717, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Ductal carcinoma in situ, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 44.3 years (16,182 days).
Specimen MBCProject_3717_T1_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Cervical; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68b92b3c-0959-43e6-842a-c294dca7118e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3717_SALIVA (Saliva), aliquot MBCProject_3717_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcf34a32-ad4f-40d4-ac07-5508c0a54479

The open-access MAF lists 378 somatic variants for this specimen: 253 protein-altering or splice-affecting, 81 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 216, Silent 81, Nonsense Mutation 26, Intron 22, 5'UTR 11, Splice Region 7, 3'UTR 5, 5'Flank 3, 3'Flank 2, Frame Shift Del 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC25A19 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs759157320, COSV57468752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 48/102 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.3205C>G p.L1069V (on ENST00000272895 / NM_173076.3; = p.L751V on NM_015657.3) | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV55975703; called by muse, mutect2, varscan2
- ACRV1 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV100223636; called by muse, mutect2, varscan2
- ADAM22 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs370626885, COSV55973954; called by muse, mutect2
- AGPAT1 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as rs765147808, COSV61248546; called by muse, mutect2
- APRT | c.174C>G p.I58M | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1445678588, COSV51939031; called by muse, mutect2, varscan2
- BCL7A | c.19C>G p.R7G | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as rs756484707, COSV55847310, COSV55849716, COSV55850251; called by muse, mutect2, varscan2
- BPIFC | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | catalogued as COSV55912100; called by muse, varscan2
- BRWD1 | c.3482C>G p.S1161* | Nonsense Mutation (SNP) | VAF 17/111 reads (15%) | catalogued as COSV100312995, COSV60898610; called by muse, mutect2, varscan2
- C11orf16 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV100393725; called by muse, mutect2, varscan2
- CACNA1I | c.4957G>A p.E1653K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1482010114; called by muse, mutect2
- CACTIN | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as COSV50267684; called by muse, varscan2
- CCDC93 | c.1184A>G p.N395S | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV60122956; called by muse, mutect2, varscan2
- CD5 | c.1301C>T p.T434M | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs145264378; called by muse, mutect2, varscan2
- CLK2 | c.223G>C p.G75R | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1459763850; called by muse, mutect2, varscan2
- CNGA4 | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV101171818; called by muse, mutect2
- COBL | c.2957G>C p.R986P | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs368670111; called by muse, mutect2, varscan2
- CYP11B1 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 89/119 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV52827694; called by muse, mutect2, varscan2
- DDR1 | c.2347G>T p.A783S (on ENST00000324771; = p.A746S on NM_001954.4) | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV104411287; called by muse, mutect2, varscan2
- DIXDC1 | c.1571G>A p.R524H (on ENST00000440460 / NM_001037954.4; = p.R313H on NM_033425.4) | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs782795755; called by muse, mutect2, varscan2
- DNAI3 | c.1192G>C p.D398H | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs776292330; called by muse, mutect2, varscan2
- DNAJC24 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as COSV101231528; called by muse, mutect2, varscan2
- DRC7 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs563865067, COSV61053397; called by muse, varscan2
- EIF2B2 | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.134); catalogued as rs776788187; called by muse, mutect2, varscan2
- EIF3B | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1328238724; called by muse, mutect2, varscan2
- EME2 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs150023204; called by muse, mutect2, varscan2
- EMP2 | c.176C>G p.S59C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV63995820; called by muse, mutect2, varscan2
- F8 | c.5317G>A p.E1773K | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as CM111357, COSV64274516; called by muse, mutect2, varscan2
- FAM71B | c.1142C>G p.T381R | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.157); catalogued as COSV57228795; called by muse, mutect2, varscan2
- FBXW10 | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs759030475, COSV57059970; called by muse, mutect2, varscan2
- FOS | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 43/254 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV57840246; called by muse, mutect2, varscan2
- FPR2 | c.933G>C p.E311D | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as rs1284602219, COSV104412244; called by muse, mutect2, varscan2
- FRMD1 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.063); catalogued as rs558803401, COSV51962821; called by muse, varscan2
- FRMD4A | c.655C>T p.H219Y | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1442685617; called by muse, mutect2, varscan2
- GCM1 | c.569G>C p.R190T | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs559949597, COSV52521430; called by mutect2, varscan2
- GPATCH4 | c.126C>G p.I42M | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100577008; called by muse, mutect2
- GTF3C5 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV59601425; called by muse, mutect2, varscan2
- HLA-C | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.101); catalogued as rs11547351, COSV100880030, COSV100880740, COSV100880756; called by muse, mutect2, varscan2
- HSPA6 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs761626559; called by muse, mutect2, varscan2
- HYOU1 | c.2933G>C p.G978A | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs906607472, COSV68215173; called by muse, mutect2
- ILK | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.066); catalogued as rs1300901328, COSV54989401, COSV54993088; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1579G>C p.V527L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.183); catalogued as COSV58019011; called by muse, mutect2
- KCNH5 | c.2620C>T p.R874C | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs754436628, COSV59753363; called by muse, mutect2, varscan2
- KDR | c.2518C>T p.L840F | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99819063; called by muse, mutect2, varscan2
- KIN | c.1086G>C p.E362D | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as COSV65430839; called by muse, mutect2, varscan2
- KLC2 | c.1414G>C p.E472Q | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1565175556; called by muse, mutect2, varscan2
- KPNA1 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1007278639, COSV100724188; called by muse, mutect2
- KRT40 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66695952; called by muse, mutect2, varscan2
- LRTM2 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.556); catalogued as rs766798117, COSV54566528; called by muse, mutect2, varscan2
- MLPH | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs11539365; called by muse, mutect2, varscan2
- MMP12 | c.965C>A p.S322Y | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV58260230; called by muse, mutect2, varscan2
- MOG | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 17/150 reads (11%) | catalogued as rs1363786126, COSV65305796; called by muse, mutect2, varscan2
- MTG2 | c.946G>C p.E316Q | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.3); catalogued as COSV100895189; called by muse, mutect2, varscan2
- NOVA1 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.953); catalogued as COSV99949050; called by muse, mutect2
- NRBP1 | c.566+5G>C | Splice Region (SNP) | VAF 10/110 reads (9%) | catalogued as rs1023250846; called by muse, varscan2
- PAF1 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs147378857; called by muse, varscan2
- PAX8 | c.7C>T p.H3Y | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.682); catalogued as COSV54511121; called by muse, varscan2
- PCDHA11 | c.192C>G p.F64L | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.564); catalogued as COSV56541558; called by muse, mutect2
- PCDHA4 | c.800C>T p.S267L | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.45); catalogued as COSV100793349, COSV100793444; called by muse, mutect2, varscan2
- PCDHB3 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 8/78 reads (10%) | catalogued as COSV50565481; called by muse, mutect2, varscan2
- PCDHB7 | c.2272G>A p.G758R | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.028); catalogued as rs548320013, COSV50826240; called by muse, mutect2, varscan2
- PCNX3 | c.3476C>T p.T1159M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs185911788, COSV99053540; called by muse, mutect2, varscan2
- PDS5A | c.3334G>A p.E1112K | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as COSV57826067; called by muse, mutect2, varscan2
- PHYHIPL | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV65848183; called by muse, varscan2
- PODXL2 | c.1180C>G p.L394V | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as rs757526600; called by muse, mutect2, varscan2
- PON3 | c.531C>G p.F177L | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55702258; called by muse, mutect2, varscan2
- PPP1R16A | c.797G>A p.W266* | Nonsense Mutation (SNP) | VAF 14/126 reads (11%) | catalogued as COSV52952330; called by muse, mutect2
- PSG11 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as rs374240794, COSV60453681, COSV60457534; called by mutect2, varscan2
- PSMB10 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs956621329, COSV99863154; called by muse, varscan2
- PTCH2 | c.3355G>A p.E1119K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs766636037; called by muse, mutect2, varscan2
- RALGPS1 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.056); catalogued as rs201112886, COSV52217859; called by mutect2, varscan2
- RSC1A1 | c.804G>T p.Q268H | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.982); catalogued as COSV60781510; called by muse, mutect2, varscan2
- SCEL | c.1462C>G p.L488V (on ENST00000349847 / NM_144777.3; = p.L468V on NM_003843.4) | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100583142, COSV62993905; called by muse, mutect2
- SEMA3A | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1340267932; called by muse, mutect2
- SETD2 | c.3002C>T p.S1001F | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV57431095; called by muse, mutect2, varscan2
- SEZ6L | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.063); catalogued as rs1219092259; called by muse, mutect2
- SGO2 | c.2611G>C p.D871H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); catalogued as COSV63417974; called by muse, mutect2, varscan2
- SHTN1 | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.938); catalogued as COSV53382065; called by muse, mutect2, varscan2
- SLC25A47 | c.108C>G p.I36M | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV64162281; called by muse, mutect2, varscan2
- SPINT1 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as rs371706199; called by muse, mutect2, varscan2
- SRCAP | c.7727C>T p.S2576L | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV52671160; called by muse, mutect2, varscan2
- ST8SIA4 | c.955G>T p.D319Y | Missense Mutation (SNP) | VAF 18/101 reads (18%) | PolyPhen possibly damaging (0.634); catalogued as COSV51508445; called by muse, mutect2, varscan2
- SYCP2 | c.4377G>A p.Q1459= | Splice Region (SNP) | VAF 14/99 reads (14%) | catalogued as rs1364779659; called by muse, mutect2, varscan2
- SYN3 | c.815G>A p.S272N | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1031636656; called by muse, mutect2, varscan2
- SYNJ1 | c.50G>A p.C17Y | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.506); catalogued as rs746182035; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THYN1 | c.113C>G p.S38C | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV55540514; called by muse, mutect2
- TLE6 | c.1363C>G p.L455V (on ENST00000246112 / NM_001143986.2; = p.L332V on NM_024760.3) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV99857956; called by muse, mutect2, varscan2
- TMEM106A | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as rs553206755, COSV59045780; called by muse, mutect2
- TOR1AIP1 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.895); catalogued as rs1458404277; called by muse, mutect2, varscan2
- TRPC4 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59005702; called by muse, mutect2, varscan2
- TTC3 | c.5800C>G p.P1934A | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1380965866; called by muse, mutect2, varscan2
- TXNDC17 | c.304-7C>G | Splice Region (SNP) | VAF 17/128 reads (13%) | catalogued as rs1567600987, COSV51514183; called by muse, mutect2, varscan2
- TYRO3 | c.1238C>T p.S413F | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.164); catalogued as rs1329746765; called by muse, mutect2, varscan2
- UQCR10 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 25/143 reads (17%) | catalogued as rs377432442, COSV57458710; called by muse, mutect2, varscan2
- USP19 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs1414836558; called by muse, mutect2, varscan2
- USP9X | c.3805G>A p.E1269K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV61067445; called by muse, mutect2, varscan2
- WAS | c.1361C>A p.S454* | Nonsense Mutation (SNP) | VAF 18/94 reads (19%) | catalogued as CM110517; called by muse, varscan2
- ZAN | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.622); catalogued as COSV100770278; called by muse, mutect2
- ZC3H12C | c.2111C>T p.P704L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs778003491, COSV53707192; called by muse, mutect2, varscan2
- ZNF175 | c.2003A>G p.E668G | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1442117448; called by muse, mutect2
- ZNF469 | c.6997G>A p.D2333N (on ENST00000437464; = p.D2361N on NM_001367624.2) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.461); catalogued as rs902061995; called by muse, mutect2, varscan2
- ZNF692 | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs766499769; called by muse, mutect2, varscan2
- ABCA2 | c.853G>C p.E285Q (on ENST00000614293; = p.E255Q on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACACB | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- ACSF2 | c.543C>G p.F181L | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ALMS1 | c.1024C>G p.L342V | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- ARL13A | c.439C>G p.L147V | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASH1L | c.8683G>A p.E2895K (on ENST00000368346 / NM_001366177.2; = p.E2890K on NM_018489.3) | Missense Mutation (SNP) | VAF 69/169 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ATAD5 | c.2724del p.K908Nfs*12 | Frame Shift Del (DEL) | VAF 13/89 reads (15%) | called by mutect2, pindel, varscan2
- ATF5 | c.667C>G p.L223V | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ATP13A5 | c.2539A>T p.M847L | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- BAZ1A | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- BLNK | c.149_152del p.R50Tfs*35 | Frame Shift Del (DEL) | VAF 38/146 reads (26%) | called by pindel, varscan2
- BNC1 | c.1146G>C p.K382N | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C8B | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CACTIN | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | called by muse, varscan2
- CCNB3 | c.4000G>A p.E1334K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- CDC23 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CDH2 | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- CFAP20DC | c.976G>C p.E326Q (on ENST00000482387 / NM_001351530.2; = p.E201Q on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- CHRNA1 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL4A3 | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COPA | c.3256G>A p.E1086K | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CPSF3 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- CPSF3 | c.753G>C p.L251F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPSF3 | c.993G>A p.M331I | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CRISPLD1 | c.707G>C p.R236T | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.197); called by muse, mutect2
- CSF1 | c.299G>C p.R100T | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- CSPP1 | c.3133C>G p.H1045D (on ENST00000676605; = p.H1004D on NM_024790.6) | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.02); called by muse, mutect2
- CTRL | c.206G>C p.W69S | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CXXC1 | c.1574+7G>A | Splice Region (SNP) | VAF 15/70 reads (21%) | called by muse, mutect2, varscan2
- DAZAP2 | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DNAJB11 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- DNAJB11 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.021); called by muse, mutect2
- DOCK3 | c.4265C>T p.A1422V | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- DOCK5 | c.4816A>T p.I1606F | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- DST | c.11909C>G p.S3970* (on ENST00000361203 / NM_001374722.1; = p.S1558* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 12/90 reads (13%) | called by muse, mutect2, varscan2
- EDEM3 | c.40C>A p.P14T | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- EDIL3 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EIF4G1 | c.2420C>A p.S807* (on ENST00000346169 / NM_198241.3; = p.S612* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 13/146 reads (9%) | called by muse, mutect2
- EPS15 | c.2350C>G p.L784V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.021); called by muse, mutect2
- ERCC3 | c.582C>G p.I194M | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- EVA1C | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXOC2 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- EXOC5 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- FADS1 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT4 | c.10734G>C p.Q3578H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FKBPL | c.456G>T p.R152S | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- FN1 | c.562G>C p.D188H | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FZD2 | c.1569C>G p.I523M | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- GASK1B | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- GJD2 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- GPD1L | c.871A>T p.K291* | Nonsense Mutation (SNP) | VAF 21/108 reads (19%) | called by muse, mutect2, varscan2
- GRIP1 | c.1557G>C p.Q519H (on ENST00000359742 / NM_001379345.1; = p.Q467H on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HGSNAT | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- HSPG2 | c.7256C>G p.S2419C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HUWE1 | c.3256C>T p.H1086Y | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- HYOU1 | c.1930G>C p.D644H | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.319); called by muse, mutect2
- IFITM5 | c.162C>A p.F54L | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.019); called by mutect2, varscan2
- IQGAP1 | c.1084C>G p.Q362E | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNQ1 | c.1940C>T p.S647F | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.271); called by mutect2, varscan2
- KIAA0825 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- KLC2 | c.1672G>C p.E558Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- KMT2D | c.9766G>A p.E3256K | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- L3MBTL3 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LCE1B | c.275G>A p.S92N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- LMNB2 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 17/100 reads (17%) | called by mutect2, varscan2
- LRPPRC | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.141); called by muse, mutect2
- LRRC37A3 | c.4228G>C p.E1410Q | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); called by muse, mutect2
- MAOA | c.582C>G p.F194L | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- MAP1A | c.2941G>T p.E981* | Nonsense Mutation (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- MAP3K21 | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.84); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MAPK8IP3 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- MON2 | c.872A>C p.Q291P | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- MX1 | c.1499G>A p.R500K | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NBR1 | c.2618C>G p.S873* | Nonsense Mutation (SNP) | VAF 14/127 reads (11%) | called by muse, mutect2, varscan2
- NHS | c.2459C>G p.S820C | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NHSL2 | c.1438G>A p.E480K (on ENST00000510661; = p.E846K on NM_001013627.2) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- NOS3 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 14/24 reads (58%) | called by muse, mutect2, varscan2
- NPAS3 | c.1442C>G p.S481C (on ENST00000356141 / NM_001164749.2; = p.S449C on NM_022123.3) | Missense Mutation (SNP) | VAF 20/219 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- NRBP1 | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- NRBP1 | c.693G>C p.K231N | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, varscan2
- NUP88 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- OAS2 | c.946C>G p.Q316E | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OGG1 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- OLFML2B | c.1558G>C p.D520H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- PARP10 | c.1003C>G p.L335V | Missense Mutation (SNP) | VAF 33/420 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.089); called by muse, mutect2
- PARP2 | c.367A>C p.N123H | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PAX9 | c.356C>G p.S119C | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PAXBP1 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.018); called by muse, mutect2
- PCDHB11 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PDE7A | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 148/189 reads (78%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PDGFD | c.65C>A p.S22Y | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.023); called by muse, mutect2
- PLA2G6 | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 21/126 reads (17%) | called by muse, mutect2, varscan2
- POMT1 | c.404G>C p.G135A | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- PPP1R16A | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.42); called by muse, mutect2
- PPP1R3G | c.695A>G p.E232G | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- PPP2R2B | c.1096G>C p.D366H (on ENST00000394409; = p.D432H on NM_181674.2) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRR14 | c.866C>A p.S289* | Nonsense Mutation (SNP) | VAF 12/97 reads (12%) | called by muse, mutect2, varscan2
- PRUNE2 | c.3418G>A p.D1140N | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PTPA | c.999+3G>A | Splice Region (SNP) | VAF 27/126 reads (21%) | called by muse, mutect2, varscan2
- PUS7L | c.1895C>G p.T632S | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2
- R3HDML | c.176C>G p.S59C | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RAB11FIP3 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RAI14 | c.779C>G p.S260C | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RBM45 | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- REEP6 | c.225G>C p.E75D | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RELN | c.9149G>A p.G3050E | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- RNF6 | c.1103C>G p.S368C | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- SAMD14 | c.419C>G p.S140C | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- SDHAF3 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SEMA3B | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (1); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- SEPHS1 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SIGLEC15 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- SLC24A3 | c.17A>T p.D6V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); called by muse, mutect2
- SLCO1B1 | c.1384G>C p.D462H | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- SNAPC2 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- SNAPC2 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 18/136 reads (13%) | called by muse, mutect2, varscan2
- SPATA20 | c.164C>A p.S55* (on ENST00000356488 / NM_001258372.1; = p.S71* on NM_022827.4) | Nonsense Mutation (SNP) | VAF 15/171 reads (9%) | called by muse, mutect2
- SRF | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STRN3 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 14/201 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); called by muse, mutect2
- STX18 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SUCO | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.253); called by muse, mutect2
- SUV39H2 | c.31+3G>T | Splice Region (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- SYNRG | c.2917C>G p.Q973E | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- TBC1D9B | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TG | c.1256C>G p.S419C | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMC7 | c.1406G>T p.C469F | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TOMM20 | c.260A>T p.E87V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- TOMM20 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- TPM4 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- TRAP1 | c.1287G>C p.Q429H | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- TRIM68 | c.1034_1036del p.N345del | In Frame Del (DEL) | VAF 18/96 reads (19%) | called by pindel, varscan2
- TTN | c.48676G>C p.E16226Q (on ENST00000591111; = p.E8802Q on NM_003319.4) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TUBGCP6 | c.5119G>T p.E1707* | Nonsense Mutation (SNP) | VAF 18/72 reads (25%) | called by muse, mutect2, varscan2
- TYW1B | c.1997C>G p.S666C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2
- UBN1 | c.2896C>G p.L966V | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- UBQLN4 | c.1264C>G p.Q422E | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- USP21 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- UTS2B | c.64T>G p.F22V | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- VCAN | c.9398C>G p.S3133C | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- VCL | c.786C>T p.D262= | Splice Region (SNP) | VAF 22/119 reads (18%) | called by muse, mutect2, varscan2
- VSIG8 | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WAS | c.1417G>A p.V473M | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, varscan2
- WDR18 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- YWHAE | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFHX4 | c.4879G>T p.E1627* | Nonsense Mutation (SNP) | VAF 7/125 reads (6%) | called by muse, mutect2
- ZFP36L1 | c.308dup p.Q104Afs*21 | Frame Shift Ins (INS) | VAF 85/211 reads (40%) | called by mutect2, pindel, varscan2
- ZMYND19 | c.606G>C p.Q202H | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ZNF267 | c.1766C>G p.S589* | Nonsense Mutation (SNP) | VAF 13/126 reads (10%) | called by muse, mutect2, varscan2
- ZNF562 | c.592C>T p.L198F (on ENST00000453372 / NM_001130032.2; = p.L126F on NM_017656.4) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF850 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ABCA2 | c.3369G>A p.K1123= (on ENST00000614293; = p.K1093= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- ABCA3 | c.2850C>G p.L950= | Silent (SNP) | VAF 19/107 reads (18%) | called by muse, mutect2, varscan2
- ADCY6 | c.114C>T p.F38= | Silent (SNP) | VAF 26/140 reads (19%) | catalogued as rs1456213505, COSV57167922; called by muse, varscan2
- ADCY6 | c.21C>T p.L7= | Silent (SNP) | VAF 19/141 reads (13%) | called by muse, varscan2
- ADRM1 | c.630G>C p.R210= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- AKT2 | c.888C>G p.L296= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as rs1382846556; called by muse, mutect2
- ANKRD39 | c.447C>G p.L149= | Silent (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
- ANKS1B | c.228C>G p.L76= | Silent (SNP) | VAF 13/97 reads (13%) | called by muse, mutect2, varscan2
- AP1M2 | c.753C>T p.R251= | Silent (SNP) | VAF 41/115 reads (36%) | catalogued as rs1281969203; called by muse, mutect2, varscan2
- APCDD1 | c.921C>T p.L307= | Silent (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- ATAD3C | c.549G>A p.K183= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV101112711; called by muse, mutect2, varscan2
- BECN1 | c.168G>A p.E56= | Silent (SNP) | VAF 20/165 reads (12%) | called by mutect2, varscan2
- C2orf78 | c.1218C>G p.G406= | Silent (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- CACNA1H | c.753C>G p.L251= | Silent (SNP) | VAF 18/82 reads (22%) | called by muse, mutect2, varscan2
- CCDC22 | c.879C>T p.F293= | Silent (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- CHST5 | c.840C>G p.L280= | Silent (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- COG7 | c.93G>A p.G31= | Silent (SNP) | VAF 16/137 reads (12%) | called by muse, mutect2, varscan2
- COL9A2 | c.1377C>T p.S459= | Silent (SNP) | VAF 24/86 reads (28%) | called by muse, varscan2
- COMP | c.1125C>T p.I375= | Silent (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- CRYBG2 | c.4839C>T p.I1613= | Silent (SNP) | VAF 13/91 reads (14%) | called by muse, mutect2, varscan2
- CYTH1 | c.1092G>A p.E364= | Silent (SNP) | VAF 28/149 reads (19%) | called by muse, mutect2, varscan2
- EPHB6 | c.1542G>A p.Q514= | Silent (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- EPPK1 | c.2541G>A p.R847= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as COSV73260921; called by muse, mutect2
- FAM133A | c.624G>A p.K208= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV59075438; called by muse, mutect2, varscan2
- FAM47A | c.852G>A p.E284= | Silent (SNP) | VAF 17/61 reads (28%) | called by muse, mutect2, varscan2
- FCRL3 | c.24G>A p.L8= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV100943488; called by muse, mutect2, varscan2
- FER1L5 | c.3750C>T p.S1250= (on ENST00000623019; = p.S1223= on NM_001293083.2) | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as rs1264508476; called by muse, mutect2
- FKBPL | c.723G>A p.L241= | Silent (SNP) | VAF 43/160 reads (27%) | called by muse, mutect2, varscan2
- FMO5 | c.837G>A p.L279= | Silent (SNP) | VAF 9/20 reads (45%) | called by muse, varscan2
- GPR179 | c.894C>G p.L298= (on ENST00000621958; = p.L297= on NM_001004334.4) | Silent (SNP) | VAF 17/81 reads (21%) | called by muse, mutect2, varscan2
- HERC2 | c.13650G>A p.L4550= | Silent (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- HPR | c.843C>T p.F281= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV57182579; called by muse, mutect2, varscan2
- IGLV7-43 | c.177G>A p.Q59= | Silent (SNP) | VAF 27/130 reads (21%) | catalogued as rs750211801; called by muse, mutect2, varscan2
- IL17RA | c.405G>A p.L135= | Silent (SNP) | VAF 22/145 reads (15%) | catalogued as rs1169409028; called by muse, mutect2, varscan2
- INSYN2A | c.441G>A p.A147= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs147680044; called by muse, mutect2, varscan2
- ITGAL | c.642G>A p.R214= | Silent (SNP) | VAF 20/187 reads (11%) | called by muse, mutect2, varscan2
- ITPRIPL2 | c.945G>A p.L315= | Silent (SNP) | VAF 11/215 reads (5%) | called by muse, mutect2
- KBTBD12 | c.930C>T p.F310= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as COSV59679871, COSV59682569; called by muse, mutect2, varscan2
- KHNYN | c.246C>A p.I82= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- KIAA1522 | c.477G>A p.R159= (on ENST00000373480 / NM_001198972.2; = p.R218= on NM_020888.3) | Silent (SNP) | VAF 21/74 reads (28%) | called by muse, mutect2, varscan2
- KIF27 | c.2685G>A p.P895= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs368455178; called by muse, mutect2, varscan2
- KLF14 | c.399C>T p.S133= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs1554470985; called by muse, mutect2, varscan2
- KLF7 | c.672C>T p.N224= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as rs201005804, COSV58743383; called by muse, mutect2, varscan2
- LOXHD1 | c.6576G>A p.Q2192= (on ENST00000642948; = p.Q2130= on NM_144612.7) | Silent (SNP) | VAF 26/185 reads (14%) | called by muse, mutect2, varscan2
- MMP17 | c.354G>A p.L118= | Silent (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- MSI2 | c.75C>T p.I25= | Silent (SNP) | VAF 36/208 reads (17%) | called by muse, varscan2
- MTBP | c.2526G>A p.L842= | Silent (SNP) | VAF 14/172 reads (8%) | called by muse, mutect2
- MTR | c.1689C>T p.V563= | Silent (SNP) | VAF 19/120 reads (16%) | called by muse, varscan2
- NABP2 | c.6G>A p.T2= | Silent (SNP) | VAF 19/141 reads (13%) | called by muse, mutect2, varscan2
- NOD1 | c.1740G>A p.K580= | Silent (SNP) | VAF 7/114 reads (6%) | called by muse, mutect2
- NR1I3 | c.426C>T p.F142= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs150598676; ClinVar: likely benign; called by muse, mutect2, varscan2
- NUP214 | c.921C>T p.L307= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV63908698; called by muse, mutect2, varscan2
- NXPE4 | c.1518C>T p.L506= (on ENST00000375478 / NM_001077639.2; = p.L222= on NM_017678.3) | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs1225561247, COSV100970296; called by muse, mutect2, varscan2
- PET100 | c.213G>A p.Q71= | Silent (SNP) | VAF 14/65 reads (22%) | called by muse, mutect2, varscan2
- PEX13 | c.747C>G p.L249= | Silent (SNP) | VAF 6/52 reads (12%) | called by mutect2, varscan2
- PKN3 | c.2034G>A p.K678= | Silent (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- PNPLA8 | c.1158G>C p.L386= | Silent (SNP) | VAF 18/101 reads (18%) | called by muse, mutect2, varscan2
- PPHLN1 | c.1167G>A p.R389= | Silent (SNP) | VAF 26/151 reads (17%) | called by muse, mutect2, varscan2
- PTPRS | c.1752G>C p.L584= | Silent (SNP) | VAF 14/66 reads (21%) | called by muse, varscan2
- RADIL | c.3225C>G p.L1075= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV68200935; called by muse, mutect2, varscan2
- RAPGEF4 | c.114G>A p.L38= | Silent (SNP) | VAF 15/77 reads (19%) | called by muse, mutect2, varscan2
- RBM34 | c.81G>C p.G27= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as rs201983997; called by muse, mutect2
- RNF214 | c.906G>A p.Q302= | Silent (SNP) | VAF 6/60 reads (10%) | called by muse, varscan2
- RTN4RL2 | c.405G>A p.S135= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs1353924881; called by muse, mutect2, varscan2
- SBSPON | c.117C>T p.R39= | Silent (SNP) | VAF 17/145 reads (12%) | called by muse, mutect2, varscan2
- SEC14L1 | c.1590C>T p.V530= | Silent (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- SH3PXD2B | c.1341C>T p.L447= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- SIPA1L2 | c.1368C>T p.S456= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as rs775181839, COSV99477592, COSV99478298; called by muse, mutect2, varscan2
- SLC4A4 | c.2484C>T p.I828= (on ENST00000264485 / NM_001098484.3; = p.I784= on NM_003759.4) | Silent (SNP) | VAF 18/103 reads (17%) | called by muse, mutect2, varscan2
- SMG5 | c.1368C>G p.L456= | Silent (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- ST7 | c.105C>T p.V35= | Silent (SNP) | VAF 120/202 reads (59%) | called by muse, mutect2, varscan2
- ST8SIA5 | c.639G>C p.V213= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV59335098; called by muse, mutect2
- STRBP | c.1218C>T p.L406= | Silent (SNP) | VAF 33/150 reads (22%) | called by muse, mutect2, varscan2
- TFR2 | c.1923C>T p.L641= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as rs760383272; called by muse, mutect2, varscan2
- UCP3 | c.282C>T p.I94= | Silent (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- UNC80 | c.8091G>A p.V2697= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs776047891; called by muse, mutect2, varscan2
- USE1 | c.12G>A p.S4= | Silent (SNP) | VAF 54/155 reads (35%) | catalogued as rs1230385312; called by muse, mutect2, varscan2
- WIZ | c.4422C>T p.F1474= (on ENST00000673675 / NM_001371589.1; = p.F379= on NM_021241.3) | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as COSV99653970; called by muse, mutect2, varscan2
- ZNF175 | c.1392C>T p.V464= | Silent (SNP) | VAF 19/109 reads (17%) | called by muse, mutect2, varscan2
- ZNF410 | c.1029C>G p.V343= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs1013117845; called by muse, mutect2, varscan2
- ZSWIM5 | c.3144C>T p.L1048= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as rs1353983972, COSV55799396, COSV55800202; called by muse, mutect2, varscan2
- AIM2 | c.*4A>T | 3'UTR (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- ALOXE3 | chr17:8118734 G>A | 5'Flank (SNP) | VAF 39/186 reads (21%) | called by muse, mutect2, varscan2
- AP1G1 | c.1088+372C>G | Intron (SNP) | VAF 14/112 reads (13%) | called by muse, mutect2, varscan2
- ARMC9 | c.1627-2686G>A | Intron (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- CCDC120 | chrX:49068627 C>T | 3'Flank (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- CFAP300 | c.-1G>C | 5'UTR (SNP) | VAF 21/90 reads (23%) | catalogued as rs948850801, COSV101462467; called by muse, mutect2, varscan2
- COASY | c.915+10G>C | Intron (SNP) | VAF 16/227 reads (7%) | called by muse, mutect2
- COQ5 | c.203-1561G>A | Intron (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- CROT | c.116-1693G>A | Intron (SNP) | VAF 25/340 reads (7%) | called by muse, mutect2
- DLG5 | c.373+1145G>A | Intron (SNP) | VAF 47/193 reads (24%) | catalogued as rs1474539990; called by muse, mutect2, varscan2
- DNMT3B | c.-206C>T | 5'UTR (SNP) | VAF 10/52 reads (19%) | catalogued as rs1035933776; called by muse, mutect2, varscan2
- DTX3 | c.-9C>T | 5'UTR (SNP) | VAF 19/172 reads (11%) | catalogued as COSV99677938; called by muse, mutect2, varscan2
- EFHB | chr3:19936243 G>A | 5'Flank (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- FRMD8P1 | n.634G>A | RNA (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- GCFC2 | c.1226+19G>T | Intron (SNP) | VAF 11/80 reads (14%) | catalogued as rs1301650804; called by muse, mutect2, varscan2
- GORAB | c.*979C>T | 3'UTR (SNP) | VAF 25/73 reads (34%) | catalogued as rs912557586; called by muse, varscan2
- H2BC7 | c.-1C>G | 5'UTR (SNP) | VAF 9/95 reads (9%) | catalogued as rs377404972; called by muse, mutect2
- HAGHL | c.288+39C>G | Intron (SNP) | VAF 21/117 reads (18%) | called by muse, mutect2, varscan2
- HIRA | c.-27C>T | 5'UTR (SNP) | VAF 16/146 reads (11%) | called by muse, mutect2, varscan2
- IGFBP3 | c.-15C>T | 5'UTR (SNP) | VAF 19/124 reads (15%) | catalogued as rs1166718927; called by muse, mutect2, varscan2
- IHO1 | chr3:49260874 C>G | 3'Flank (SNP) | VAF 33/126 reads (26%) | called by muse, mutect2, varscan2
- LIMK2 | c.1773-1301C>T | Intron (SNP) | VAF 45/211 reads (21%) | catalogued as rs1242175543, COSV99313926; called by muse, mutect2, varscan2
- MAP1LC3A | c.-87G>C | 5'UTR (SNP) | VAF 4/46 reads (9%) | catalogued as rs1418370166, COSV54164902; called by muse, mutect2
- PLA2G6 | c.426-26C>T | Intron (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- PLCD3 | c.1712-41C>T | Intron (SNP) | VAF 18/46 reads (39%) | catalogued as rs776732308; called by muse, mutect2, varscan2
- PLEKHA7 | c.-4G>A | 5'UTR (SNP) | VAF 21/79 reads (27%) | called by muse, mutect2, varscan2
- POLR2C | c.387+58C>G | Intron (SNP) | VAF 21/102 reads (21%) | called by muse, mutect2, varscan2
- RASGRP2 | c.*6+17C>A | Intron (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2
- RNFT2 | c.84-1122G>A | Intron (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- RPAIN | c.631-895C>A | Intron (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2, varscan2
- RRP7A | c.*3874G>A | 3'UTR (SNP) | VAF 25/87 reads (29%) | catalogued as rs766236553; called by muse, mutect2, varscan2
- SLC29A1 | chr6:44223612 C>G | 5'Flank (SNP) | VAF 11/114 reads (10%) | called by muse, mutect2
- SREBF1 | c.2736-18C>T | Intron (SNP) | VAF 22/76 reads (29%) | called by muse, varscan2
- THSD4 | c.-80+15099C>T | Intron (SNP) | VAF 9/117 reads (8%) | called by muse, mutect2
- TMEM135 | c.-22C>T | 5'UTR (SNP) | VAF 33/251 reads (13%) | catalogued as rs1446758222; called by muse, mutect2, varscan2
- TRIM36 | c.63+2210C>T | Intron (SNP) | VAF 12/88 reads (14%) | catalogued as rs1010186360; called by muse, mutect2
- TRIM36 | c.63+2208C>T | Intron (SNP) | VAF 14/88 reads (16%) | called by muse, mutect2
- TTC8 | c.-42C>G | 5'UTR (SNP) | VAF 7/62 reads (11%) | catalogued as rs770165064; called by muse, mutect2
- TXNDC9 | c.*5C>G | 3'UTR (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- UHRF1 | c.-10-1282C>T | Intron (SNP) | VAF 9/78 reads (12%) | catalogued as rs1387710738; called by muse, mutect2, varscan2
- UMPS | c.*5150G>C | 3'UTR (SNP) | VAF 5/23 reads (22%) | called by mutect2, varscan2
- USE1 | c.394+137G>A | Intron (SNP) | VAF 51/152 reads (34%) | called by muse, mutect2, varscan2
- ZNF274 | c.-15G>C | 5'UTR (SNP) | VAF 9/109 reads (8%) | called by muse, mutect2
- ZNF44 | c.147+1986G>C | Intron (SNP) | VAF 15/77 reads (19%) | called by muse, mutect2, varscan2
